Surgical pathology report (de-identified scan), TCGA case TCGA-66-2786, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2786-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right upper lobe, among others

Clinical diagnosis and question

Squamous cell carcinoma of the right upper lobe.

REPORT ON FINDINGS**Macroscopy**

- 1.) Right upper lobe: inflated, fixed right upper pulmonary lobe measuring 18 x 12 x 4 cm, central bronchus resection plane located 0.1 cm proximal to the bifurcation into the segmental bronchi. At the hilus a 2 cm node. A staple suture line runs from the hilus in a caudoventral direction for 10 cm. Visceral pleura, especially in the lateral region, shows slightly reticulate blackish pigmentation. In S2 and 3, at the boundary to S1 a firm, pale gray tumor, max. 2.8 cm in size, with central patchy blackish pigmentation and unclear, in parts vaguely arcuate demarcation. Distance from visceral pleura 0.5 cm. Subsegmental branches of B2 and B3 leading into the tumor. Rest of parenchyma accentuated in S1 showing rarefaction with formation of lacunae of max. 1 cm.
- 2.) Lobar LN (station 12) lower lobe: 0.7 cm node.
- 3.) Hilar LN (station 10) right: 0.7 cm node with surrounding tissue.
- 4.) Low paratracheal LN (station 4) right: 0.8 cm lesioned node and a 0.5 cm node with abundant surrounding tissue.
- 5.) Subcarinal LN (station 7): 1.6 cm lesioned node or node part with some surrounding tissue.

Examined:

- 1.) a: Tumor with pleura, b: tumor with subsegmental branch B2, c: tumor with subsegmental branch B3, d: S1 apical, e: bronchus and vessel resection margins (tangential), f: hilar node (lamellated),
- 2.) - 5.) All material (in 5.) lamellated),
- 10 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION**Primary diagnosis/diagnoses:**

Intermediate bronchopulmonary, histologically poorly differentiated, large-cell, focal gigantocellular, nonkeratinizing squamous cell carcinoma of the right upper lobe of the lung located in the boundary region of S2 and 3.

TNM classification according to this picture pT1 pN0 pMX R0, stage IA. C 34.1, M 8070/3.

Secondary diagnosis/diagnoses:

Marked focal centroacinar pulmonary emphysema (sample 1.)). Lymph nodes with reactive lesions and anthracotic pigment deposits (samples 1.) to 5.)).

[page 2 of 2]
Remark/addendum:

The carcinoma has evidently grown partly into the alveolar septa and in many places is covered by the preserved hyperplastic alveolar epithelium, possibly as a result of this there are evidently extracellular accumulations of mucus in the tumor and between the tumor cell structures, in the sense of mucus retention, without any unequivocal mucin formation discernible in the tumor. The visceral pleura, resection margin of the bronchus and vessels and all excised lymph nodes are tumor-free.

Source: NCI Genomic Data Commons file cea0428b-c138-4651-b560-11090c084d56 (TCGA-66-2786.1F8077D2-EFA8-4E09-B4A2-E848C3723278.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).